Somatic mutation profile of tumor specimen C3L-01286-02 (aliquot CPT0086950009) from CPTAC case C3L-01286, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 58.7 years (21,429 days).
Specimen C3L-01286-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26b76bea-6904-4678-971a-b9750b8282f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01286-31 (Blood Derived Normal), aliquot CPT0087450002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aae8f0bc-3e47-4f96-a078-65a1b9421feb

The open-access MAF lists 108 somatic variants for this specimen: 77 protein-altering or splice-affecting, 18 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 18, Intron 5, 3'UTR 4, Frame Shift Del 4, Nonsense Mutation 4, In Frame Del 3, Splice Region 2, 5'Flank 2, Splice Site 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3641G>A p.R1214H | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as rs750194005, COSV66583891; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD24 | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs758342016; called by muse, varscan2
- CCDC42 | c.932A>G p.Q311R | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs781345210; called by muse, mutect2, varscan2
- CDH22 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.855); catalogued as rs926295661; called by muse, mutect2, varscan2
- CEP295 | c.3763G>C p.D1255H | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV57349476; called by muse, mutect2, varscan2
- CPLX2 | c.89C>A p.A30E | Missense Mutation (SNP) | VAF 46/304 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs1334772726; called by muse, mutect2, varscan2
- DAAM1 | c.2164G>T p.D722Y | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1419113038; called by muse, mutect2, varscan2
- EIF2B2 | c.922G>T p.V308L | Missense Mutation (SNP) | VAF 211/438 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.092); catalogued as CM152520, COSV56720257; called by muse, mutect2, varscan2
- FBP2 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs201943366; called by muse, mutect2, varscan2
- HGFAC | c.1948C>T p.R650W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as rs577434025, COSV66977323; called by muse, mutect2, varscan2
- KCNH7 | c.1820G>C p.G607A | Missense Mutation (SNP) | VAF 77/195 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1169469826, COSV59790106; called by muse, mutect2, varscan2
- KIAA0319L | c.393A>T p.L131F | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs41310436, COSV57843171, COSV57844099; called by muse, mutect2, varscan2
- KRT2 | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 117/467 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1330514030; called by muse, mutect2, varscan2
- OR2L2 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 61/286 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.02); catalogued as rs753145578, COSV63551776; called by muse, mutect2, varscan2
- OR52N1 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 102/479 reads (21%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.859); catalogued as COSV57693368, COSV57693885; called by muse, mutect2, varscan2
- PAGR1 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.109); catalogued as COSV56188506; called by muse, mutect2, varscan2
- PATL1 | c.1630C>G p.L544V | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.028); catalogued as COSV55693559; called by muse, mutect2, varscan2
- PCNX3 | c.4855C>T p.R1619C | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758077741, COSV63136005; called by muse, mutect2, varscan2
- PCSK5 | c.1939G>A p.G647R | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1406686253, COSV65084371; called by muse, mutect2, varscan2
- QSER1 | c.1886C>T p.S629L (on ENST00000399302; = p.S758L on NM_001076786.3) | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV67899550; called by muse, mutect2, varscan2
- REST | c.1823T>C p.M608T | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1387308478; called by muse, mutect2, varscan2
- SETD2 | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as COSV57434480, COSV57448778; called by muse, mutect2, varscan2
- ST18 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs141556653; called by muse, mutect2, varscan2
- TERT | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 171/417 reads (41%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1554042981; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNRC18 | c.3296T>C p.L1099P | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1174060554; called by muse, mutect2, varscan2
- TTC33 | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 66/343 reads (19%) | catalogued as rs374271035; called by muse, mutect2, varscan2
- TTLL10 | c.477C>A p.F159L (on ENST00000379289 / NM_001130045.2; = p.F86L on NM_153254.3) | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV64959736; called by muse, mutect2, varscan2
- ABCA10 | c.4533+2T>A p.X1511_splice | Splice Site (SNP) | VAF 26/156 reads (17%) | called by muse, mutect2, varscan2
- ACAA1 | c.569A>G p.E190G | Missense Mutation (SNP) | VAF 98/164 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- AKAP6 | c.1944A>C p.E648D | Missense Mutation (SNP) | VAF 80/319 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- ANKS1B | c.2261T>A p.V754D | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- C16orf89 | c.1091T>C p.L364P | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1R | c.1449del p.A484Pfs*61 (on ENST00000536053 / NM_001354346.2; = p.A470Pfs*61 on NM_001733.7) | Frame Shift Del (DEL) | VAF 52/460 reads (11%) | called by mutect2, pindel
- CAPN9 | c.402G>A p.Q134= | Splice Region (SNP) | VAF 20/110 reads (18%) | called by muse, varscan2
- CARMIL1 | c.3177G>T p.K1059N | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CEP290 | c.826A>T p.K276* | Nonsense Mutation (SNP) | VAF 22/42 reads (52%) | called by muse, varscan2
- CYFIP1 | c.2567G>A p.C856Y | Missense Mutation (SNP) | VAF 80/227 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- DMD | c.2243C>A p.A748E | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- DPCD | c.247_259del p.L83Afs*14 | Frame Shift Del (DEL) | VAF 22/168 reads (13%) | called by pindel, varscan2
- E2F1 | c.645G>T p.E215D | Missense Mutation (SNP) | VAF 36/295 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EFCAB5 | c.1275G>C p.R425S | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- EFR3B | c.1654del p.L552Sfs*49 | Frame Shift Del (DEL) | VAF 57/250 reads (23%) | called by mutect2, pindel, varscan2
- EMILIN3 | c.1826C>A p.S609Y | Missense Mutation (SNP) | VAF 95/223 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- EML5 | c.3586G>T p.V1196L | Missense Mutation (SNP) | VAF 71/194 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- FLT1 | c.1184dup p.T396Nfs*2 | Frame Shift Ins (INS) | VAF 102/345 reads (30%) | called by mutect2, pindel, varscan2
- FYB1 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); called by muse, mutect2
- HEY1 | c.647A>G p.Q216R | Missense Mutation (SNP) | VAF 67/272 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- HHIPL2 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 271/464 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- IL6ST | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 148/387 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- JUP | c.848_853delinsG p.K283Sfs*37 | Frame Shift Del (DEL) | VAF 64/437 reads (15%) | called by pindel, varscan2*
- KIAA1614 | c.2105T>A p.F702Y | Missense Mutation (SNP) | VAF 231/411 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- KIAA1841 | c.1208A>T p.Y403F | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KISS1 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 387/660 reads (59%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTBP1 | c.2344G>A p.E782K (on ENST00000404816 / NM_206943.4; = p.E456K on NM_000627.4) | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- MAP3K19 | c.3535G>T p.E1179* | Nonsense Mutation (SNP) | VAF 49/262 reads (19%) | called by muse, mutect2, varscan2
- MGAT3 | c.773C>G p.T258S | Missense Mutation (SNP) | VAF 101/136 reads (74%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NIPAL3 | c.93+7del | Splice Region (DEL) | VAF 38/123 reads (31%) | called by mutect2, pindel, varscan2
- NOP53 | c.1374-2A>T p.X458_splice | Splice Site (SNP) | VAF 69/250 reads (28%) | called by muse, mutect2, varscan2
- NPIPB2 | c.491A>T p.K164I (on ENST00000399147; = p.K24I on NM_001355514.1) | Missense Mutation (SNP) | VAF 92/418 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR9G4 | c.623T>C p.L208P | Missense Mutation (SNP) | VAF 64/267 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PBRM1 | c.4853_4864del p.S1618_S1621del (on ENST00000296302 / NM_001366071.2; = p.S1511_S1514del on NM_018313.5) | In Frame Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- PHF20 | c.2580G>T p.R860S | Missense Mutation (SNP) | VAF 344/488 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PLXNC1 | c.1900T>C p.C634R | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNC1 | c.2116G>T p.D706Y | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PROX2 | c.1760C>T p.S587F (on ENST00000556489 / NM_001243007.1; = p.S360F on NM_001080408.2) | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- S100A10 | c.51C>A p.H17Q | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); called by muse, mutect2
- SEH1L | c.46C>G p.H16D | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SLC17A7 | c.435_440del p.R145_F147delinsS | In Frame Del (DEL) | VAF 88/181 reads (49%) | called by mutect2, pindel, varscan2
- SPACA1 | c.731G>C p.W244S | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- SPARCL1 | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TRMT5 | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 82/422 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- VPS13B | c.1312A>G p.M438V | Missense Mutation (SNP) | VAF 96/391 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- WDR41 | c.1127G>A p.S376N | Missense Mutation (SNP) | VAF 82/274 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR91 | c.359A>T p.Q120L | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZBTB3 | c.1024T>A p.S342T | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZMYM5 | c.1390_1404del p.E464_Q468del | In Frame Del (DEL) | VAF 40/198 reads (20%) | called by mutect2, pindel, varscan2
- ZNF114 | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.33); called by muse, mutect2
- ALMS1 | c.1977G>A p.T659= | Silent (SNP) | VAF 52/211 reads (25%) | catalogued as rs201316401; ClinVar: likely benign; called by muse, mutect2, varscan2
- B3GALT1 | c.198T>C p.L66= | Silent (SNP) | VAF 68/134 reads (51%) | called by muse, mutect2, varscan2
- CACNA1H | c.5685C>T p.D1895= | Silent (SNP) | VAF 34/128 reads (27%) | catalogued as rs1463806903, COSV52356542; called by muse, mutect2, varscan2
- CPA5 | c.681G>T p.L227= | Silent (SNP) | VAF 40/205 reads (20%) | catalogued as COSV62568748; called by muse, mutect2, varscan2
- CTAGE15 | c.1257G>A p.V419= | Silent (SNP) | VAF 137/682 reads (20%) | catalogued as rs1455939379; called by muse, mutect2, varscan2
- GNPTAB | c.2466C>G p.T822= | Silent (SNP) | VAF 40/171 reads (23%) | called by muse, mutect2, varscan2
- GPAT2 | c.1188C>T p.G396= | Silent (SNP) | VAF 96/179 reads (54%) | catalogued as rs746992961; called by muse, mutect2, varscan2
- HCRTR1 | c.999C>T p.R333= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs200222372; called by muse, mutect2, varscan2
- ITIH1 | c.1275G>A p.R425= | Silent (SNP) | VAF 47/86 reads (55%) | called by muse, mutect2, varscan2
- LHX5 | c.33C>T p.P11= | Silent (SNP) | VAF 60/203 reads (30%) | catalogued as rs897376357; called by muse, mutect2, varscan2
- MCM10 | c.1389G>A p.G463= (on ENST00000484800 / NM_182751.3; = p.G462= on NM_018518.5) | Silent (SNP) | VAF 75/247 reads (30%) | called by muse, mutect2, varscan2
- METTL25 | c.1668C>T p.P556= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV50261609; called by muse, mutect2, varscan2
- PER1 | c.3609G>A p.V1203= | Silent (SNP) | VAF 13/53 reads (25%) | called by muse, varscan2
- SLC9A9 | c.1113G>A p.L371= | Silent (SNP) | VAF 67/186 reads (36%) | called by muse, varscan2
- VNN2 | c.1287C>T p.F429= | Silent (SNP) | VAF 32/128 reads (25%) | called by muse, mutect2, varscan2
- WDR41 | c.1128C>T p.S376= | Silent (SNP) | VAF 82/280 reads (29%) | called by muse, mutect2, varscan2
- ZBTB46 | c.84C>T p.G28= | Silent (SNP) | VAF 175/226 reads (77%) | catalogued as rs368634130; called by muse, mutect2, varscan2
- ZNF777 | c.1017C>T p.R339= | Silent (SNP) | VAF 56/280 reads (20%) | catalogued as rs373973043; called by muse, mutect2, varscan2
- CRISPLD2 | c.240+31C>A | Intron (SNP) | VAF 59/254 reads (23%) | called by muse, mutect2, varscan2
- DENND2C | c.*18A>G | 3'UTR (SNP) | VAF 22/58 reads (38%) | catalogued as rs201437846; called by muse, mutect2, varscan2
- E2F6 | c.164-1628C>A | Intron (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- MIR124-2 | chr8:64378189 G>A | 5'Flank (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- MMP9 | c.1902-16C>G | Intron (SNP) | VAF 79/566 reads (14%) | called by muse, mutect2, varscan2
- RAX2 | c.*19C>A | 3'UTR (SNP) | VAF 38/171 reads (22%) | catalogued as rs1391595572; called by muse, mutect2, varscan2
- RECQL4 | c.-41T>C | 5'UTR (SNP) | VAF 8/30 reads (27%) | catalogued as rs1564813478; called by muse, mutect2, varscan2
- SCFD1 | c.613+604C>T | Intron (SNP) | VAF 47/204 reads (23%) | called by muse, mutect2, varscan2
- SNORD114-31 | chr14:100990169 A>G | 5'Flank (SNP) | VAF 28/103 reads (27%) | catalogued as rs745746858; called by muse, varscan2
- SOX5 | c.*1010C>A | 3'UTR (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- SPATA7 | c.190+37T>G | Intron (SNP) | VAF 46/209 reads (22%) | called by muse, mutect2, varscan2
- TMEM134 | c.*30_*39del | 3'UTR (DEL) | VAF 51/247 reads (21%) | called by mutect2, pindel, varscan2
- TPM1 | chr15:63069969 G>A | 3'Flank (SNP) | VAF 84/318 reads (26%) | catalogued as rs747553234; called by muse, mutect2, varscan2
